Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EU, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EU-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Esophagus, middle third
C15.4
JW 11/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus (Mid third)

PATHOLOGY REPORT:

1.
Specimen: Esophagus and proximal stomach
Procedure: Esophagogastrectomy
Tumor site: esophagus
Tumor size (greatest dimension): 4.2 cm
Histologic type: Squamous cell carcinoma
Histologic grade: G2 moderately differentiated
Microscopic tumor extension: tumor invades through submucosa
Lymph-vascular invasion: not identified
Perineural invasion: not identified
Peritumoral desmoplasia scarce
Moderate peritumoral lymphocitary infiltrate
Gastric mucosa congested
Margins: uninvolved by carcinoma
Regional lymph nodes:
Number examined: 13 (right paracardics 0/1; left paracardics 1/2; lesser
curvature of stomach 0/6; celiac trunk 1/4)
Number positive for neoplasia: 02
2. "Periesophageal lymph nodes":
Number examined: 01
Number positive for neoplasia: 00
3. "Esophageal margin":
Uninvolved by carcinoma.

Criteria	W 10/24/13	Yes	No
ICD-O Discrepancy			✓

Source: NCI Genomic Data Commons file 37b19147-4857-4164-9e2a-06b43a85ecb8 (TCGA-VR-A8EU.37CB2EC5-68B7-4392-A78A-9674FDDC51BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).